Somatic mutation profile of tumor specimen TCGA-DV-5569-01A (aliquot TCGA-DV-5569-01A-01D-1534-10) from TCGA case TCGA-DV-5569, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 29.3 years (10,698 days).
Specimen TCGA-DV-5569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02dc4192-301a-4893-b065-4a09f93f7d38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5569-10A (Blood Derived Normal), aliquot TCGA-DV-5569-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3775b6cb-c693-4156-8649-1d577d15883f

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2D | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV56438423; called by muse, mutect2, varscan2
- CTNNAL1 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | catalogued as COSV57706291; called by muse, mutect2
- DYNC2H1 | c.12073A>G p.I4025V | Missense Mutation (SNP) | VAF 199/681 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1417472286, COSV62106036; called by muse, mutect2, varscan2
- MUC16 | c.37780T>A p.S12594T | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV67491275; called by muse, mutect2, varscan2
- MYOF | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1291332519, COSV63710261; called by muse, mutect2, varscan2
- SLC22A25 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs777266043, COSV60594582; called by muse, mutect2, varscan2
- SMPD2 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57806980; called by muse, mutect2
- SNRNP200 | c.5066G>A p.G1689D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60494259; called by muse, mutect2, varscan2
- SYNE3 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1317181535, COSV62082471; called by muse, mutect2, varscan2
- TRIOBP | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs4821700; ClinVar: likely benign / benign; called by muse, varscan2
- NOTCH1 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- BGN | c.954C>T p.N318= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1357283426, COSV59038305; called by muse, mutect2, varscan2
- HNRNPH1 | c.1260C>T p.Y420= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs767516103, COSV61485087, COSV61485758; called by muse, mutect2
- NCOR1 | c.4113C>T p.V1371= | Silent (SNP) | VAF 42/403 reads (10%) | catalogued as rs1315536413, COSV51994945; called by muse, mutect2, varscan2
- TAX1BP1 | c.153T>G p.G51= | Silent (SNP) | VAF 56/247 reads (23%) | catalogued as COSV55296738; called by muse, mutect2, varscan2
